Gene-level copy-number profile of tumor specimen ALCH-ADR9-TTP1-A from ALCHEMIST case ALCH-ADR9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.5 years (19,894 days).
Specimen ALCH-ADR9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e5eac72c-9afe-4f09-b157-9e9a9e6de77f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADR9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/b470bb3e-d646-496a-a043-e83f48f57649

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,265; copy number 2: 53,170; copy number 3: 2,106; copy number 4: 250; copy number 5: 7; copy number 6: 40; copy number 7: 35; copy number 19: 42.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 124 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:24,810,024–28,581,511, 88 genes, copy number 6–19 (broad region; genes not listed).
- chr12:87,944,885–88,199,887, 7 genes, copy number 5: RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3.
- chr12:117,208,142–117,452,170, 1 gene, copy number 6 (within-gene range 3–6): NOS1.
- chr12:117,453,012–119,163,051, 28 genes, copy number 6: AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1, TAOK3, RPS2P5, AC026367.1, SUDS3, AC026367.3, AC026367.2, LINC02460, RPL17P37, LINC02423, LINC02440, LINC02439, RNA5SP374, AC087863.2, AC087863.1, SRRM4, AC087885.1, RN7SL508P, AC084361.1.

Autosomal genes at a single copy (total copy number 1): 563. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
